Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WI, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WI-01A (Primary Tumor).

ICD-O-3

Oligoastrocytoma, grade II
9382/3

Site Brain, supratentorial NOS
C71.0

JW 8/12/13

Translation

glioma with astrocytic and oligodendroglial
differentiation

proliferation increased but still compatible with
grade II

Diagnosis

oligoastrocytoma WHO grade II

Untranslated full report is
housed at the BCR.

Criteria	JW 7/16/13	Yes	No
II/AA Discrepancy			
Site Malignancy History			
Assess (circle):	QUALIFIED	D'SQUALIFIED	

Source: NCI Genomic Data Commons file 411d4ab5-f659-4c14-9e1f-763503cd8c70 (TCGA-S9-A6WI.7C8D177B-28E8-4306-A5C4-104D2F2C00E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).